TCGA case TCGA-97-7546 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d90c9f3-5025-4867-a2f0-e455b6a254fa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (2)
1. Acinar cell carcinoma (the primary disease): ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.4 years (27,913 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 1,255 days (3.4 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 1,255 days (3.4 years); Days to treatment end: 1,255 days (3.4 years); Course number: 1; Treatment anatomic sites: Primary Tumor Field.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 79.9 years (29,168 days); Days to diagnosis: 1,255 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.

Follow-up (2 entries)
- Days to follow up: 964 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,285 days (3.5 years); Disease response: With Tumor.

Other clinical attributes
- DLCO (% of predicted): 60; FEV1/FVC after bronchodilator (%): 96; FEV1/FVC before bronchodilator (%): 100; FEV1 after bronchodilator (% of reference): 84; FEV1 before bronchodilator (% of reference): 85.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 1983.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-7546-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-97-7546-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 65; Percent normal cells: 4; Percent necrosis: 1; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5.
- Sample TCGA-97-7546-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-97-7546-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Acinar Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: Yes.
- Drug treatment: Pharmaceutical therapy drug name: Tarceva.
- Radiation treatment: Radiation type other: Direct to the Spot.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, New neoplasm event types: New tumor event type: New Primary Tumor.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,285 days; disease-specific survival: no event (censored), 1,285 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,255 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-7546-01A-11D-2035-01): tumor purity 0.67, ploidy 1.85, whole-genome doublings 0.
